Somatic mutation profile of tumor specimen TCGA-L5-A88W-01A (aliquot TCGA-L5-A88W-01A-11D-A351-09) from TCGA case TCGA-L5-A88W, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: GX; Age at diagnosis: 67.7 years (24,716 days).
Specimen TCGA-L5-A88W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 591bef30-fdd9-4a89-b0fe-de69dd21d73c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A88W-11A (Solid Tissue Normal), aliquot TCGA-L5-A88W-11A-11D-A351-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/dce5dc06-261c-45de-80cf-6d09c1afba91

The open-access MAF lists 149 somatic variants for this specimen: 116 protein-altering or splice-affecting, 29 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 98, Silent 29, Nonsense Mutation 6, Frame Shift Del 5, Frame Shift Ins 5, Splice Site 2, Intron 2, 3'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 25/94 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SMARCA4 | c.2729C>T p.T910M | Missense Mutation (SNP) | VAF 20/56 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1238758086, COSV60785486, COSV60802491; ClinVar: other / uncertain significance; called by muse, mutect2, varscan2
- TGFBR2 | c.1276G>A p.A426T | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs863223849, CM086983, COSV55453442; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TNNI3 | c.61C>T p.R21C | Missense Mutation (SNP) | VAF 43/120 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs267607128, CM034574; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA10 | c.3361A>G p.I1121V | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.074); catalogued as rs753945392, COSV52226758; called by muse, mutect2
- AC104452.1 | c.581C>T p.T194I | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.232); catalogued as rs758774866; called by muse, mutect2, varscan2
- ADAM7 | c.2239G>A p.A747T | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.001); catalogued as rs367681847, COSV99443175; called by muse, mutect2, varscan2
- ADI1 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); catalogued as rs771440115; called by muse, mutect2, varscan2
- ARHGAP33 | c.3353C>T p.S1118F | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); catalogued as COSV50121216, COSV99139436; called by muse, mutect2, varscan2
- ARHGEF15 | c.1964C>T p.S655L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.043); catalogued as rs867056869, COSV62725961; called by muse, mutect2, varscan2
- ATAD2 | c.4030dup p.S1344Kfs*28 | Frame Shift Ins (INS) | VAF 25/76 reads (33%) | catalogued as rs775812316; called by mutect2, varscan2
- BRD3 | c.889G>A p.E297K | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs531283531, COSV57706354; called by muse, mutect2
- CAPN5 | c.291C>G p.I97M (on ENST00000456580; = p.I57M on NM_004055.5) | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as COSV99582477; called by muse, mutect2
- CD101 | c.2792C>T p.S931L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1403208435; called by muse, mutect2
- CELA2A | c.163T>C p.Y55H | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.022); catalogued as rs1249648802; called by muse, mutect2, varscan2
- CHD7 | c.4432G>A p.E1478K | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.324); catalogued as COSV71113706; called by muse, mutect2, varscan2
- COL11A1 | c.2101C>T p.L701F | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as rs771448295, COSV62202539; called by muse, mutect2, varscan2
- COLEC12 | c.1733G>C p.G578A | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1459310372, COSV101232129, COSV68372143; called by muse, mutect2, varscan2
- EPHA2 | c.1876G>T p.E626* | Nonsense Mutation (SNP) | VAF 13/37 reads (35%) | catalogued as COSV64453930; called by muse, mutect2, varscan2
- FREM2 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.146); catalogued as rs553605556, COSV99748916; called by muse, mutect2, varscan2
- GIMAP2 | c.389A>C p.K130T | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.962); catalogued as rs754733684, COSV56234303; called by muse, mutect2, varscan2
- GTF2H3 | c.906G>T p.K302N | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs755944714, COSV57459456; called by muse, mutect2, varscan2
- HIPK2 | c.581C>G p.S194C | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs900697694; called by muse, mutect2, varscan2
- HTT | c.5879G>A p.R1960H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as rs762436871; called by muse, mutect2, varscan2
- ICE1 | c.4526G>A p.R1509H | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as rs749575254, COSV99663307; called by muse, mutect2, varscan2
- IFTAP | c.363G>T p.L121F | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.077); catalogued as rs1274921727; called by muse, mutect2, varscan2
- KANSL1 | c.1043G>A p.R348Q | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1159013744, COSV99294158; called by muse, mutect2, varscan2
- KBTBD3 | c.62C>G p.P21R | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.323); catalogued as COSV73241213; called by muse, mutect2, varscan2
- KIR2DL4 | c.278G>A p.R93H (on ENST00000396284; = p.R54H on NM_001080770.2) | Missense Mutation (SNP) | VAF 40/144 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs370135620; called by muse, varscan2
- KMT2D | c.15326G>T p.C5109F | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM105471, COSV56477525; called by muse, mutect2, varscan2
- LAMA5 | c.9632C>T p.T3211M | Missense Mutation (SNP) | VAF 68/185 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.616); catalogued as rs763726733; called by muse, mutect2, varscan2
- LMAN2 | c.895C>T p.L299F | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (1); PolyPhen possibly damaging (0.816); catalogued as rs1188903851; called by muse, mutect2, varscan2
- MTOR | c.6094G>A p.E2032K | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV63872070; called by muse, mutect2, varscan2
- NKX2-5 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.112); catalogued as rs1365219269, COSV61298358; called by muse, mutect2, varscan2
- NTNG1 | c.1501C>T p.R501W (on ENST00000370068 / NM_001113226.3; = p.R400W on NM_014917.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV64274760; called by muse, mutect2
- PIDD1 | c.1465C>G p.R489G | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as COSV61705893; called by muse, mutect2, varscan2
- PIP5K1A | c.1673C>T p.S558L (on ENST00000368888 / NM_001135638.2; = p.S545L on NM_003557.3) | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1028690083, COSV62957523; called by muse, mutect2, varscan2
- PLCB1 | c.1682G>C p.R561T | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV62040461; called by muse, mutect2, varscan2
- PSG6 | c.956G>A p.R319H | Missense Mutation (SNP) | VAF 86/274 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.027); catalogued as rs148457672; called by muse, mutect2, varscan2
- PSMC3 | c.790G>T p.G264C | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54081297; called by muse, mutect2, varscan2
- RABGAP1L | c.1842T>G p.D614E | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1336936865; called by muse, mutect2, varscan2
- RAC1 | c.97A>T p.I33F | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.861); catalogued as COSV61824916; called by muse, mutect2
- SLC16A8 | c.228C>A p.S76R | Missense Mutation (SNP) | VAF 40/107 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs867259330; called by muse, mutect2, varscan2
- SPOP | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV61652768; called by muse, mutect2, varscan2
- SYCP2 | c.4208G>A p.S1403N | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as rs760667527; called by muse, mutect2, varscan2
- SYNM | c.2811G>A p.M937I | Missense Mutation (SNP) | VAF 21/47 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1234961699; called by muse, mutect2, varscan2
- TANC2 | c.4154C>T p.P1385L | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as rs1188684495; called by muse, mutect2, varscan2
- TET3 | c.5221G>A p.G1741R | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1025529920; called by muse, mutect2, varscan2
- TULP4 | c.3361C>G p.P1121A | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs758491143, COSV65581002; called by muse, mutect2, varscan2
- USP47 | c.3760G>A p.E1254K (on ENST00000399455 / NM_001372095.1; = p.E1166K on NM_017944.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 57/139 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.935); catalogued as rs752493697; called by muse, mutect2, varscan2
- VARS1 | c.3370G>A p.D1124N | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.58); catalogued as rs913501174; called by muse, mutect2, varscan2
- ZNF492 | c.1159C>T p.H387Y | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71762156; called by muse, mutect2, varscan2
- ADAM7 | c.8C>A p.P3H | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.431); called by muse, mutect2, varscan2
- ADRA2C | c.1360C>T p.R454* | Nonsense Mutation (SNP) | VAF 18/77 reads (23%) | called by muse, mutect2, varscan2
- AGO1 | c.1583-1G>A p.X528_splice | Splice Site (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- ASXL2 | c.14_21del p.G5Efs*25 | Frame Shift Del (DEL) | VAF 26/110 reads (24%) | called by mutect2, pindel, varscan2
- CCDC106 | c.519G>T p.R173S | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCDC136 | c.2933C>G p.A978G | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CEP70 | c.1214C>T p.S405F | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CFAP52 | c.440C>G p.A147G | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- CYLD | c.1827-1G>T p.X609_splice | Splice Site (SNP) | VAF 27/112 reads (24%) | called by muse, mutect2, varscan2
- DDX60 | c.2000G>T p.S667I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- DONSON | c.1501_1535del p.Y501Pfs*8 | Frame Shift Del (DEL) | VAF 25/115 reads (22%) | called by mutect2, pindel
- DYRK1A | c.969G>C p.Q323H | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FBXO3 | c.1309G>C p.D437H | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- GATB | c.1366G>T p.D456Y | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- GPR179 | c.5753G>C p.R1918T (on ENST00000621958; = p.R1917T on NM_001004334.4) | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- HLA-A | c.227_230dup p.E77Dfs*23 | Frame Shift Ins (INS) | VAF 11/72 reads (15%) | called by mutect2, varscan2
- HPX | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- IFT22 | c.490T>C p.Y164H | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- IGKV1D-17 | c.260G>A p.S87N | Missense Mutation (SNP) | VAF 76/225 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- ITIH2 | c.1963del p.L655Cfs*23 | Frame Shift Del (DEL) | VAF 31/87 reads (36%) | called by mutect2, pindel, varscan2
- KIF13B | c.3394G>C p.E1132Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- KIF20B | c.5160C>A p.N1720K (on ENST00000371728 / NM_001284259.2; = p.N1680K on NM_016195.4) | Missense Mutation (SNP) | VAF 31/98 reads (32%) | SIFT tolerated (0.91); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LRBA | c.5904G>A p.W1968* | Nonsense Mutation (SNP) | VAF 23/71 reads (32%) | called by muse, mutect2, varscan2
- LRP2 | c.7194G>C p.L2398F | Missense Mutation (SNP) | VAF 35/89 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- LTBP3 | c.1975G>A p.V659M | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- MAS1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- MBTPS2 | c.1138dup p.S380Kfs*28 | Frame Shift Ins (INS) | VAF 26/44 reads (59%) | called by mutect2, varscan2
- MFSD5 | c.8T>C p.V3A | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- MGA | c.2793T>A p.H931Q | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MGRN1 | c.1068T>G p.C356W | Missense Mutation (SNP) | VAF 12/210 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2
- NAALADL1 | c.1504C>T p.P502S | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NLRP4 | c.683T>G p.F228C | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPHP3 | c.1078del p.S360Vfs*3 | Frame Shift Del (DEL) | VAF 53/153 reads (35%) | called by mutect2, pindel, varscan2
- NRK | c.3814C>G p.L1272V | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NSD2 | c.3872dup p.S1292Ffs*14 | Frame Shift Ins (INS) | VAF 23/88 reads (26%) | called by mutect2, pindel, varscan2
- OR5AS1 | c.148A>G p.N50D | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- OR8D2 | c.817G>C p.V273L | Missense Mutation (SNP) | VAF 35/86 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.377); called by muse, mutect2
- PCDHA4 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PLCE1 | c.1973A>T p.K658I | Missense Mutation (SNP) | VAF 29/75 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- PROSER3 | c.427C>G p.Q143E | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PXDNL | c.798T>G p.I266M | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RPL3 | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RPL8 | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- S1PR1 | c.649A>G p.I217V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SACS | c.4129A>T p.T1377S | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SLC15A2 | c.209A>G p.Y70C | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLC9A8 | c.593C>A p.S198Y | Missense Mutation (SNP) | VAF 34/97 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SORCS3 | c.1393G>A p.D465N | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- SPAG5 | c.3400G>A p.E1134K | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- STON1 | c.731C>G p.S244* | Nonsense Mutation (SNP) | VAF 21/54 reads (39%) | called by muse, mutect2, varscan2
- TBC1D15 | c.1945_1954del p.V649Lfs*37 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | called by mutect2, pindel, varscan2
- TGM5 | c.2074G>A p.G692R (on ENST00000220420 / NM_201631.4; = p.G610R on NM_004245.4) | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM254 | c.121C>G p.Q41E | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT tolerated (0.33); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TPTE2 | c.979A>T p.T327S (on ENST00000400230 / NM_199254.2; = p.T250S on NM_130785.3) | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRIM35 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- TRIM56 | c.569G>C p.R190T | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.409); called by muse, mutect2, varscan2
- TTC29 | c.526G>A p.D176N | Missense Mutation (SNP) | VAF 18/76 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- UBE2D2 | c.388G>C p.D130H | Missense Mutation (SNP) | VAF 38/86 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- UNC13A | c.3669G>T p.K1223N | Missense Mutation (SNP) | VAF 22/66 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2, varscan2
- WWC1 | c.568C>A p.R190S | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2
- ZFC3H1 | c.4103dup p.Y1369Vfs*8 | Frame Shift Ins (INS) | VAF 17/81 reads (21%) | called by mutect2, pindel, varscan2
- ZNF354C | c.1435C>T p.Q479* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | called by muse, mutect2, varscan2
- ZNF480 | c.1235C>G p.S412* | Nonsense Mutation (SNP) | VAF 22/66 reads (33%) | called by muse, mutect2, varscan2
- AC004593.2 | c.630C>T p.Y210= | Silent (SNP) | VAF 11/49 reads (22%) | called by muse, mutect2, varscan2
- AMY1C | c.960T>C p.H320= | Silent (SNP) | VAF 52/323 reads (16%) | catalogued as rs756303606, COSV100915214; called by muse, mutect2, varscan2
- BCL9L | c.1323G>A p.G441= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as rs1217579386; called by muse, mutect2
- CAV2 | c.75C>G p.L25= | Silent (SNP) | VAF 44/128 reads (34%) | called by muse, mutect2, varscan2
- CCIN | c.1455G>A p.R485= | Silent (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- DICER1 | c.3984C>T p.T1328= | Silent (SNP) | VAF 14/54 reads (26%) | called by muse, mutect2, varscan2
- DSCAM | c.5043C>A p.R1681= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV68032865; called by muse, mutect2, varscan2
- EFR3A | c.1338A>T p.G446= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as COSV54460321; called by muse, mutect2, varscan2
- EIF2D | c.594C>G p.L198= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as rs782300669; called by muse, mutect2, varscan2
- FLNC | c.4041C>T p.G1347= | Silent (SNP) | VAF 15/57 reads (26%) | called by muse, mutect2, varscan2
- IFT140 | c.4089C>T p.L1363= | Silent (SNP) | VAF 13/41 reads (32%) | called by muse, mutect2, varscan2
- ITK | c.570C>T p.L190= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs764897415; called by muse, mutect2, varscan2
- KIF15 | c.291C>T p.C97= | Silent (SNP) | VAF 27/92 reads (29%) | called by muse, mutect2, varscan2
- MYT1 | c.1569G>A p.E523= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as COSV60511149; called by muse, mutect2, varscan2
- NBEAL1 | c.6894C>T p.D2298= | Silent (SNP) | VAF 27/72 reads (38%) | catalogued as rs765999889; called by muse, mutect2, varscan2
- NPHP4 | c.3657G>T p.L1219= | Silent (SNP) | VAF 26/72 reads (36%) | called by muse, mutect2, varscan2
- OR6C65 | c.636G>T p.V212= | Silent (SNP) | VAF 13/72 reads (18%) | called by muse, mutect2, varscan2
- PLCG2 | c.1623G>A p.T541= | Silent (SNP) | VAF 30/96 reads (31%) | catalogued as rs772797149, COSV100842695, COSV63866977; called by muse, mutect2, varscan2
- RNF135 | c.1275G>A p.L425= | Silent (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
- SAMD4B | c.1644G>A p.Q548= | Silent (SNP) | VAF 24/59 reads (41%) | called by muse, mutect2, varscan2
- SELENBP1 | c.972C>T p.F324= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as rs923601693; called by muse, mutect2, varscan2
- SLC6A12 | c.1095C>T p.I365= | Silent (SNP) | VAF 26/54 reads (48%) | catalogued as rs771756771, COSV62885102; called by muse, mutect2, varscan2
- SP7 | c.42C>T p.S14= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV58191396; called by muse, mutect2, varscan2
- TAF7 | c.504A>G p.R168= | Silent (SNP) | VAF 8/27 reads (30%) | called by muse, mutect2, varscan2
- TBL2 | c.510G>A p.E170= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV59786776; called by muse, mutect2, varscan2
- THAP11 | c.564C>T p.I188= | Silent (SNP) | VAF 23/50 reads (46%) | called by muse, mutect2, varscan2
- TRPA1 | c.3225C>T p.I1075= | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as rs1261157454; called by muse, mutect2, varscan2
- TSR1 | c.1293G>A p.E431= | Silent (SNP) | VAF 18/57 reads (32%) | catalogued as rs980689186; called by muse, mutect2, varscan2
- WASF3 | c.774G>T p.L258= | Silent (SNP) | VAF 49/167 reads (29%) | called by muse, mutect2, varscan2
- BMP1 | c.731-148C>A | Intron (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- ETFB | c.58-12C>T | Intron (SNP) | VAF 14/48 reads (29%) | catalogued as rs1440001995; called by muse, mutect2, varscan2
- IL23R | c.*1A>G | 3'UTR (SNP) | VAF 23/44 reads (52%) | catalogued as COSV61375279; called by muse, mutect2, varscan2
- REXO1L1P | n.1505C>A | RNA (SNP) | VAF 16/364 reads (4%) | called by muse, mutect2
